MMRF case MMRF_2214 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/0ca48821-c238-4e18-a7aa-a650c3fb5e20

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 75 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 75.9 years (27,714 days); ISS stage: II; Days to last known disease status: 758 days (2.1 years); Days to last follow up: 758 days (2.1 years).
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 426 days (1.2 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 433 days (1.2 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 9 days; Days to treatment end: 36 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 44 days; Days to treatment end: 433 days (1.2 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -5 (ECOG 1): M Protein 7.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 770 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.57 mg/dL; Immunoglobulin G 82.6 g/L; Immunoglobulin A 0.27 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 4.64 µg/mL; Lactate Dehydrogenase 3.27 µkat/L; Hemoglobin 4.77 mmol/L; Leukocytes 11.2 ×10⁹/L; Absolute Neutrophil 9.7 ×10⁹/L; Platelets 147 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.5 mmol/L; Albumin 32 g/L; Total Protein 12.4 g/dL; Glucose 4.57 mmol/L.
- Day 79 (ECOG 1): M Protein 2.8 g/dL; Immunoglobulin G 31.9 g/L; Immunoglobulin A 0.11 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 5.89 mmol/L; Leukocytes 8.6 ×10⁹/L; Absolute Neutrophil 7.8 ×10⁹/L; Platelets 304 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 8.2 g/dL; Glucose 6.93 mmol/L.
- Day 188 (ECOG 1): M Protein 0.9 g/dL; Immunoglobulin G 13.6 g/L; Immunoglobulin A 0.57 g/L; Hemoglobin 5.7 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 131 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 2.5 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 6.5 g/dL; Glucose 4.4 mmol/L.
- Day 283 (ECOG 1): M Protein 0.5 g/dL; Immunoglobulin G 9.31 g/L; Immunoglobulin A 0.95 g/L; Immunoglobulin M 0.21 g/L; Hemoglobin 6.39 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 201 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.2 mmol/L; Albumin 36 g/L; Total Protein 5.5 g/dL; Glucose 4.79 mmol/L.
- Day 366 (ECOG 1): M Protein 0.5 g/dL; Immunoglobulin G 8.5 g/L; Hemoglobin 7.07 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 187 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.23 mmol/L; Albumin 37 g/L; Total Protein 6 g/dL; Glucose 5.17 mmol/L.
- Day 450 (ECOG 1): M Protein 0.3 g/dL; Immunoglobulin G 9.96 g/L; Immunoglobulin A 1.85 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 8.12 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 275 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.43 mmol/L; Albumin 39 g/L; Total Protein 6.4 g/dL; Glucose 6 mmol/L.
- Day 510 (ECOG 2): M Protein 0.5 g/dL; Immunoglobulin G 9.27 g/L; Immunoglobulin A 1.77 g/L; Immunoglobulin M 0.25 g/L; Hemoglobin 7.75 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 242 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.38 mmol/L; Albumin 37 g/L; Total Protein 6.5 g/dL; Glucose 4.68 mmol/L.
- Day 569: M Protein 0.4 g/dL; Immunoglobulin G 12.9 g/L; Immunoglobulin A 2.43 g/L; Immunoglobulin M 0.46 g/L; Hemoglobin 8.93 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 277 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.4 mmol/L; Albumin 42 g/L; Total Protein 7 g/dL; Glucose 4.84 mmol/L.
- Day 700: M Protein 1.1 g/dL; Immunoglobulin G 17.6 g/L; Immunoglobulin A 2.6 g/L; Immunoglobulin M 0.52 g/L; Hemoglobin 8.8 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 275 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.38 mmol/L; Albumin 39 g/L; Total Protein 7.4 g/dL; Glucose 6.22 mmol/L.
- Day 758 (ECOG 1): M Protein 2.3 g/dL; Immunoglobulin G 28.6 g/L; Immunoglobulin A 1.88 g/L; Immunoglobulin M 0.38 g/L; Hemoglobin 8.62 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 228 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.3 mmol/L; Albumin 36 g/L; Total Protein 8.2 g/dL; Glucose 4.79 mmol/L.

Other clinical attributes
- Day -5: Weight: 91 kg; Height: 172 cm.

Biospecimens (2 samples)
- Sample MMRF_2214_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -5 days.
- Sample MMRF_2214_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -5 days.
